Surgical pathology report (de-identified scan), TCGA case TCGA-BR-4280, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-4280-01A (Primary Tumor).

STOMACH TISSUE CHECKLIST Specimen type: Gastrectomy Tumor site: Stomach Tumor size: 6 x 5 x 2.5 cm Tumor features: None specified
Histologic type: Adenocarcinoma Histologic grade: Moderately differentiated Tumor extent: Subserosa Lymph nodes: 1/6 positive for
metastasis (Perigastric 1/6) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Not
specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

Source: NCI Genomic Data Commons file 44eaf76c-ef8e-462d-b350-cd0e89203d90 (TCGA-BR-4280.D947CF63-E879-455E-BE15-A29826345DAE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).